Somatic mutation profile of tumor specimen TCGA-VM-A8CA-01A (aliquot TCGA-VM-A8CA-01A-11D-A36O-08) from TCGA case TCGA-VM-A8CA, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 54.7 years (19,991 days).
Specimen TCGA-VM-A8CA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f80cdf5c-5322-4e20-85d9-6fc41a5b867f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VM-A8CA-10A (Blood Derived Normal), aliquot TCGA-VM-A8CA-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cf7c55f-aad6-4aec-aae4-cbcdb7159144

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Nonsense Mutation 2, 5'Flank 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 48/80 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APOBEC3F | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.371); catalogued as rs374582155; called by muse, mutect2, varscan2
- COL12A1 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1319038184, COSV100485987; called by muse, mutect2, varscan2
- DDX23 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as COSV99974763; called by muse, mutect2
- FAM47A | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as rs758012443, COSV100649888; called by muse, mutect2, varscan2
- KRT84 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99230870; called by muse, mutect2, varscan2
- LRP5 | c.4033A>G p.S1345G | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV99591978; called by muse, mutect2, varscan2
- LTN1 | c.3732G>A p.W1244* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100797999; called by muse, mutect2, varscan2
- MAP1A | c.3634G>A p.V1212I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100288652; called by muse, mutect2, varscan2
- OR52A5 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs1406225971, COSV100263444; called by muse, mutect2, varscan2
- PHB2 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99781090; called by muse, mutect2
- SETD4 | c.1028C>A p.T343K | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100145622; called by muse, mutect2
- SIRT5 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 22/275 reads (8%) | catalogued as COSV100702832; called by muse, mutect2
- TAOK2 | c.3409C>T p.P1137S | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99663050; called by muse, mutect2, varscan2
- TMC3 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770347299, COSV100845911; called by muse, mutect2, varscan2
- VTCN1 | c.344T>C p.L115S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100061713; called by muse, mutect2, varscan2
- ZNF614 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs115005123, COSV54547942; called by muse, mutect2, varscan2
- GLG1 | c.3380del p.P1127Qfs*12 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel
- AGAP1 | c.570C>T p.I190= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs576969179, COSV58323086; called by muse, mutect2, varscan2
- ARHGAP12 | c.930A>G p.Q310= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs745742281, COSV100260594; called by muse, mutect2, varscan2
- RBBP8NL | c.1824C>T p.H608= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs199665028, COSV99436606; called by muse, mutect2, varscan2
- RORB | c.1026A>G p.K342= (on ENST00000396204 / NM_001365023.1; = p.K331= on NM_006914.4) | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100974335; called by muse, mutect2
- NDUFV1 | chr11:67604987 G>A | 5'Flank (SNP) | VAF 5/15 reads (33%) | catalogued as rs1356909010; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1338G>T | RNA (SNP) | VAF 10/100 reads (10%) | called by muse, varscan2
